Somatic mutation profile of tumor specimen TARGET-30-PAIVHE-01A (aliquot TARGET-30-PAIVHE-01A-01W) from TARGET case TARGET-30-PAIVHE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.1 years (1,123 days).
Specimen TARGET-30-PAIVHE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0820c889-8e0f-4a09-9b31-1e28e3e4dea2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIVHE-10A (Blood Derived Normal), aliquot TARGET-30-PAIVHE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8f8de59-28d7-4238-a834-f4d70293a35d

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4A | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62161880; called by muse, mutect2, varscan2
- BCAS1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV65083596; called by muse, mutect2, varscan2
- CALHM2 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53294144; called by muse, mutect2, varscan2
- EP400 | c.2520G>T p.E840D | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as COSV57761882; called by muse, mutect2, varscan2
- FBN2 | c.4690T>A p.L1564M | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV52490813; called by muse, mutect2, varscan2
- FRRS1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.041); catalogued as COSV54920129; called by muse, mutect2, varscan2
- HAND2 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64017619; called by muse, mutect2, varscan2
- HNMT | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV54505829; called by muse, mutect2, varscan2
- ITGA7 | c.1426G>A p.E476K (on ENST00000555728; = p.E432K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV57691320; called by muse, mutect2, varscan2
- LMNTD1 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 131/548 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51444455; called by muse, mutect2, varscan2
- OR10AG1 | c.608T>A p.L203Q | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56631227; called by muse, mutect2, varscan2
- PIK3R6 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs371755231; called by muse, mutect2, varscan2
- PPP2CB | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV55327989; called by muse, mutect2, varscan2
- SPTA1 | c.4132G>T p.D1378Y | Missense Mutation (SNP) | VAF 23/864 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV63751445, COSV63762173; called by muse, mutect2
- STK36 | c.1818A>C p.K606N | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55324159; called by muse, mutect2, varscan2
- SYNE1 | c.4421C>T p.T1474I (on ENST00000367255 / NM_182961.4; = p.T1481I on NM_033071.3) | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV54898914; called by muse, mutect2, varscan2
- TLE6 | c.556C>T p.L186= (on ENST00000246112 / NM_001143986.2; = p.L63= on NM_024760.3) | Splice Region (SNP) | VAF 59/153 reads (39%) | catalogued as COSV55734239, COSV55736713; called by muse, mutect2, varscan2
- VEPH1 | c.1985T>A p.M662K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV62875535; called by muse, mutect2, varscan2
- ZNF283 | c.307T>G p.L103V | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV60288342; called by muse, mutect2, varscan2
- ZNF436 | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV58357949; called by muse, mutect2, varscan2
- KMT2A | c.11521_11522insACCC p.R3841Hfs*7 | Frame Shift Ins (INS) | VAF 45/152 reads (30%) | called by pindel, varscan2
- NEBL | c.1712A>C p.Y571S | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- PNPO | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by mutect2, varscan2
- CNTNAP4 | c.771C>G p.T257= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- FAM169A | c.600G>A p.E200= | Silent (SNP) | VAF 182/749 reads (24%) | catalogued as COSV65845899, COSV65846898; called by muse, mutect2, varscan2
- FLAD1 | c.1107C>T p.L369= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs150738412, COSV52695637, COSV99421793; called by muse, mutect2, varscan2
- ICAM5 | c.390C>A p.P130= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV53423191; called by muse, mutect2, varscan2
- KNSTRN | c.411A>G p.K137= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV51103370; called by muse, mutect2, varscan2
- OR2B3 | c.795C>A p.S265= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV65850703; called by muse, mutect2, varscan2
- TRIML2 | c.846C>A p.G282= | Silent (SNP) | VAF 51/176 reads (29%) | catalogued as COSV58714428; called by muse, mutect2, varscan2
- LSM3 | c.-1C>T | 5'UTR (SNP) | VAF 25/249 reads (10%) | catalogued as rs763051710; called by muse, mutect2, varscan2
